Somatic mutation profile of tumor specimen MBCProject_0381_T1_WES (aliquot MBCProject_0381_T1_WES_1) from CMI case MBCProject_0381, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 46.0 years (16,805 days).
Specimen MBCProject_0381_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76edb356-7656-4411-94d5-4941ac026ff3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0381_SALIVA (Saliva), aliquot MBCProject_0381_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69668c15-0a47-4885-8b8b-928faae1f6e8

The open-access MAF lists 34 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Intron 3, 5'UTR 1, 5'Flank 1, In Frame Ins 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2313_2324dup p.Y772_A775dup | In Frame Ins (INS) | VAF 10/26 reads (38%) | hotspot (GDC flag); catalogued as rs397516975; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATXN1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV55207186; called by muse, mutect2, varscan2
- CDH1 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55735735, COSV55745602; called by muse, mutect2, varscan2
- CGRRF1 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs749268741; called by muse, mutect2, varscan2
- HIPK4 | c.1343A>G p.N448S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs367871526; called by muse, mutect2, varscan2
- KATNIP | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs187220970; called by muse, mutect2, varscan2
- MYH9 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53392598; called by muse, mutect2, varscan2
- NEK1 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs778982890; called by mutect2, varscan2
- NRXN3 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.049); catalogued as rs201052888; called by muse, mutect2, varscan2
- PEX7 | c.689A>G p.N230S | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.084); catalogued as rs984236887; called by muse, mutect2, varscan2
- RBM41 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 28/134 reads (21%) | catalogued as COSV52564766; called by muse, mutect2, varscan2
- ZDHHC5 | c.1240A>G p.K414E | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as rs1270219692; called by muse, mutect2, varscan2
- ZNF467 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs771923748, COSV57373183; called by muse, mutect2, varscan2
- B4GALNT2 | c.1406C>G p.T469S | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C11orf80 | c.60G>C p.K20N | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- C11orf80 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- ESF1 | c.825_845del p.D275_D281del | In Frame Del (DEL) | VAF 28/80 reads (35%) | called by mutect2, pindel*, varscan2
- MTOR | c.1954G>T p.V652L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- OR7D4 | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC2A12 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XKR7 | c.1371G>T p.K457N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZZZ3 | c.2551G>A p.D851N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); called by muse, varscan2
- CEACAM19 | c.798G>A p.L266= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- KLRG1 | c.318A>G p.R106= | Silent (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- KRTAP5-6 | c.174G>A p.G58= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as rs200046995; called by muse, varscan2
- RTEL1 | c.1557C>G p.G519= | Silent (SNP) | VAF 37/94 reads (39%) | called by muse, mutect2, varscan2
- TENM4 | c.3687C>G p.L1229= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs549762416, COSV53680088; called by muse, varscan2
- TMEM80 | c.390C>T p.L130= (on ENST00000526170 / NM_001276274.1; = p.L192= on NM_174940.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as rs1215797106, COSV59347525; called by muse, mutect2, varscan2
- UCP2 | c.756C>T p.S252= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs908818175; called by muse, mutect2, varscan2
- CHTF8 | chr16:69132501 G>A | 5'Flank (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- DTNBP1 | c.811+109A>G | Intron (SNP) | VAF 14/44 reads (32%) | catalogued as rs768829840; called by muse, mutect2, varscan2
- GNB5 | c.864-500T>A | Intron (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- REV3L | c.9043-618T>A | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as rs1356395055; called by muse, varscan2
- VAMP3 | c.-61C>A | 5'UTR (SNP) | VAF 56/178 reads (31%) | called by muse, mutect2, varscan2
